Somatic mutation profile of tumor specimen 0DRVOX from CCDI case PBBZSI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Granulosa cell tumor, juvenile; Tissue or organ of origin: Ovary; Age at diagnosis: 7.4 years (2,694 days).
Specimen 0DRVOX: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7622147-2bbc-460e-84e8-bd068ec7c764.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRVP0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/985c2faf-b195-4809-beb5-e7236df7afb1

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFT74 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 137/439 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1564012501; called by muse, mutect2, varscan2
- USH2A | c.9461C>T p.A3154V | Missense Mutation (SNP) | VAF 21/782 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV56367712; called by muse, mutect2
- API5 | c.1454G>A p.S485N | Missense Mutation (SNP) | VAF 19/588 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- PCM1 | c.788G>C p.R263T | Missense Mutation (SNP) | VAF 93/349 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VWA8 | c.21C>A p.L7= | Silent (SNP) | VAF 68/272 reads (25%) | called by muse, mutect2, varscan2
- GRK7 | c.-83G>A | 5'UTR (SNP) | VAF 8/41 reads (20%) | catalogued as rs186188558; called by muse, mutect2, varscan2
